Somatic mutation profile of tumor specimen 0DXXY3 from CCDI case PBCPDR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Giant cell tumor of soft parts, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 4.2 years (1,552 days).
Specimen 0DXXY3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3236b1d4-b0dc-4305-853c-b42c68df6542.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXXW3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/352b77ff-a1d7-47b9-99dd-dd71905db209

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 5, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MKI67 | c.4716G>C p.K1572N | Missense Mutation (SNP) | VAF 43/907 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); catalogued as COSV100896191; called by muse, mutect2
- ADGRB3 | c.3367A>G p.K1123E | Missense Mutation (SNP) | VAF 106/634 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC40 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 147/586 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- MAPT | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 96/449 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MILR1 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 103/540 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- WDR25 | c.142C>A p.Q48K | Missense Mutation (SNP) | VAF 12/305 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2
- ATXN7L3 | c.12G>A p.E4= | Silent (SNP) | VAF 70/324 reads (22%) | catalogued as rs1338516251; called by muse, mutect2, varscan2
- FAM169A | c.1725G>T p.G575= | Silent (SNP) | VAF 16/418 reads (4%) | catalogued as rs1372139977; called by muse, mutect2
- PORCN | c.471C>A p.G157= | Silent (SNP) | VAF 18/494 reads (4%) | catalogued as COSV58227247; called by muse, mutect2
- TK1 | c.159C>T p.I53= | Silent (SNP) | VAF 178/743 reads (24%) | called by muse, mutect2, varscan2
- TMUB2 | c.597G>A p.L199= (on ENST00000538716 / NM_001353177.2; = p.L179= on NM_024107.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 85/464 reads (18%) | called by muse, mutect2, varscan2
- IPO8 | c.-90C>A | 5'UTR (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- RAB37 | c.432+91C>A | Intron (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
